Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A48J, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A48J-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Amended/Addendum *

Patient:

[REDACTED]

Physician:

Date of Receipt:

Date of Amendment:

[REDACTED]

....

Clinical Diagnosis & History:

Abdominal sarcoma (path: well differentiated and smooth muscle neoplasm).

Specimens Submitted:

1: SP: Retroperitoneal sarcoma and vena cava

ICD-O3
leiomyosarcoma, NOS 8890/3

Site: Retroperitoneum

4-11-12

C48.0

RD

AMENDED DIAGNOSIS:

- 1) SOFT TISSUE, RETROPERITONEUM; EXCISION:
- HIGH GRADE LEIOMYOSARCOMA, 22 X 15 X 10 CM, FOCALLY EXTENDING TO SURGICAL MARGIN.
- TUMOR IS ADHERENT TO THE SEGMENT OF INFERIOR VENA CAVA.
- TUMOR NECROSIS IS PRESENT (20%).

Note:

This document represents an amended version of the surgical pathology report originally issued on [REDACTED] That report, although, retained in the clinical chart for record purposes, is superseded by the present document. The amendment consists of the following change:

AMENDED REPORT:

THERE IS NO ADDENDUM FOR THIS REPORT.

The responsible clinician has been notified.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	CD117	
	CD34	
	SMA	
	des	

** Continued on next page **

[page 2 of 4]
SURGICAL

Page 2 of 4

Gross Description:

1) The specimen is received fresh, labeled "Retroperitoneal sarcoma and vena cava (stitch marks vena cava)". It consists of a large multilobulated tan-pink mass measuring 22 x 15 x 10 cm and weighing 1700 grams. The mass is partially covered by a tan-pink membrane. A stitch is identified indicating the vena cava. The margins of resection are inked black. A portion of a previously opened vena cava is adherent to the mass measuring 5 x 2.5 cm. The inner lining of the vena cava is tan-white and smooth. On one edge of the mass is a portion of exposed necrotic area measuring 9 x 5 x 3 cm. The inked margin is inked blue. The specimen is serially sectioned revealing a multilobulated tan-pink to white-gray focally hemorrhagic, focally necrotic whorled cut surface with areas of myxoid changes. The area of necrosis comprises about 20% of the entire tumor mass. Sections submitted for TPS. Photographs of the specimen are taken. Representative sections are submitted.

Summary of sections:

VC vena cava

VCT vena cava and adjacent tumor

NT necrotic tumor

T tumor

SM surgical margin

Summary of Sections:

Part 1: SP: Retroperitoneal sarcoma and vena cava

Block	Sect.	Site	PCs
2		NT	4
5		SM	10
15		T	30
1		VC	2
3		VCT	3

Amendments

Amend Date:

Amended By:

Original Diagnosis:

1) SOFT TISSUE, RETROPERITONEUM; EXCISION:

** Continued on next page **

[page 3 of 4]
SURGICAL [REDACTED]

----- Page 3 of 4
- HIGH GRADE LEIOMYOSARCOMA, 22 X 15 X 10 CM, FOCALLY EXTENDING TO
SURGICAL MARGIN.
- TUMOR IS ADHERENT TO THE SEGMENT OF INFERIOR VENA CAVA.
- TUMOR NECROSIS IS PRESENT (20%).

*** Report Electronically Signed Out ***
Signed out by

Amend Date: Amended By:

Previous Diagnosis:
ADDENDUM

SITE: LYMPH NODE, RIGHT NECK, EXCISION

IMMUNOHISTOCHEMICAL STUDIES SHOW THAT THE REED STERNBERG CELLS ARE POSITIVE
FOR CD15 AND CD30, AND NEGATIVE FOR CD20. THIS SUPPORTS THE DIAGNOSIS.

*** Report Electronically Signed Out ***
Signed out by

Procedures/Addenda:
Addendum

Date Ordered:	Stat:
Date Complete:	By:
Date Reported:	* Amended *

Addendum Diagnosis

THERE IS NO ADDENDUM FOR THIS REPORT

Amendments for Addendum

Amended:
Reason: Clerical Error
Case given to amendment due to addendum being
typed in error.
Previous Signout Date:

** Continued on next page **

[page 4 of 4]
SURGICAL

Page 4 of 4

Referring Physician Contacted

** End of Report **

WJ 10/12

Source: NCI Genomic Data Commons file a8658b63-2856-4177-a8c8-3dd0f4d63652 (TCGA-DX-A48J.351642E8-9C46-4A09-8D2A-D68466232127.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).